Gene-level copy-number profile of specimen HCM-CSHL-0811-C55-85A from HCMI case HCM-CSHL-0811-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G3.
Specimen HCM-CSHL-0811-C55-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f04488e4-27b8-4e0f-b8a2-2e6d837986b8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0811-C55-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/5de9faa6-f957-4f53-a3d5-3fdce1f8944c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 341; copy number 2: 14,754; copy number 3: 26,945; copy number 4: 12,543; copy number 5: 1,334; copy number 6: 1,998; copy number 7: 79; copy number 8: 132; copy number 9: 26; copy number 10: 127; copy number 11: 5; copy number 12: 17; copy number 13: 82; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 469 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,638,745–9,746,869, 4 genes, copy number 8–9 (within-gene range 5–9): AC082651.1, AC082651.4, RNU4-73P, AC082651.2.
- chr2:90,100,236–90,115,402, 2 genes, copy number 7 (within-gene range 6–7): IGKV1D-16, IGKV3D-15.
- chr2:90,179,889–90,367,699, 9 genes, copy number 7–8: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr5:134,114,681–134,151,865, 1 gene, copy number 7 (within-gene range 3–7): TCF7.
- chr13:98,610,292–98,641,239, 3 genes, copy number 10: NUS1P4, CYCSP35, CALM2P4.
- chr14:18,614,388–18,633,634, 3 genes, copy number 9 (within-gene range 6–9): CR383656.6, ARHGAP42P5, LINC02297.
- chr14:18,634,955–18,637,421, 2 genes, copy number 9 (within-gene range 6–9): CR383656.1, CR383656.12.
- chr16:46,469,341–46,790,407, 13 genes, copy number 7 (within-gene range 5–7): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr17:20,185,082–22,070,538, 86 genes, copy number 10–12 (within-gene range 2–12) (broad region; genes not listed).
- chr17:31,851,871–31,901,708, 3 genes, copy number 7: COPRS, UTP6, AC004253.1.
- chr19:29,901,696–30,957,192, 14 genes, copy number 7–14: AC008798.1, AC008507.3, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:32,581,190–39,182,816, 313 genes, copy number 7–13 (broad region; genes not listed).
- chr20:62,550,453–62,570,764, 1 gene, copy number 8 (within-gene range 6–8): MIR1-1HG.
- chr20:62,564,912–62,762,771, 14 genes, copy number 8: MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2.
- chr22:21,141,624–21,142,371, 1 gene, copy number 9: E2F6P2.

Autosomal genes at a single copy (total copy number 1): 341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
